Somatic mutation profile of tumor specimen ALCH-B4ZK-TTP1-A (aliquot ALCH-B4ZK-TTP1-A-1-0-D-A83F-36) from ALCHEMIST case ALCH-B4ZK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.8 years (23,316 days).
Specimen ALCH-B4ZK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d88ac2e-78f4-494a-91ea-fe8a22d2f51e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4ZK-NB1-A (Blood Derived Normal), aliquot ALCH-B4ZK-NB1-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcb07597-a81b-442b-811b-2e0e1a07156d

The open-access MAF lists 65 somatic variants for this specimen: 47 protein-altering or splice-affecting, 12 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 12, Nonsense Mutation 4, Intron 3, 5'Flank 1, In Frame Del 1, 5'UTR 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.6259G>A p.G2087R | Missense Mutation (SNP) | VAF 11/340 reads (3%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553153748, COSV61371196, COSV61381160; ClinVar: other; called by muse, mutect2
- ATM | c.4957C>T p.Q1653* | Nonsense Mutation (SNP) | VAF 42/532 reads (8%) | catalogued as rs1565469955, COSV53759616; ClinVar: pathogenic; called by muse, mutect2
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 9/86 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 120/879 reads (14%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel
- APOB | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 34/336 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1255501488; called by muse, mutect2
- ATP7B | c.4241C>T p.P1414L | Missense Mutation (SNP) | VAF 68/784 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs374693153; called by muse, mutect2
- CCDC166 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0.017); catalogued as rs1554616678, COSV72638919; called by muse, mutect2
- DRAXIN | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 46/468 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs758315246, COSV53843821; called by muse, mutect2
- DYDC1 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 26/372 reads (7%) | catalogued as COSV100942967; called by muse, mutect2
- ERP27 | c.544T>C p.Y182H | Missense Mutation (SNP) | VAF 46/370 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs199876317; called by muse, mutect2, varscan2
- IGKV2D-29 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 36/564 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs754547041; called by muse, mutect2
- LAMA2 | c.9017G>C p.G3006A | Missense Mutation (SNP) | VAF 19/711 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70351955, COSV70357767; called by muse, mutect2
- PPP2R3B | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs750780998; called by muse, mutect2, varscan2
- SIGLEC1 | c.2393G>A p.R798H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as rs762450727; called by muse, mutect2
- SIGLEC8 | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 27/290 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.298); catalogued as rs373970607; called by muse, mutect2
- SIRPB1 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 78/827 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV53537699; called by muse, mutect2
- USP9X | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 30/548 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV61067054; called by muse, mutect2
- VWA5A | c.2347A>G p.I783V | Missense Mutation (SNP) | VAF 61/484 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1168218909; called by muse, mutect2, varscan2
- WBP11 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated, low confidence (0.58); PolyPhen possibly damaging (0.462); catalogued as rs535254129, COSV53762397, COSV53763601; called by muse, mutect2
- WDFY4 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 23/243 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147299795; called by muse, mutect2
- ARHGAP21 | c.3892dup p.L1298Pfs*26 | Frame Shift Ins (INS) | VAF 11/96 reads (11%) | called by pindel, varscan2
- ARMCX2 | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.034); called by muse, mutect2
- ATRX | c.2909A>G p.K970R | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.024); called by muse, mutect2
- ATXN2L | c.3019C>T p.Q1007* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- BMP2K | c.845A>G p.D282G | Missense Mutation (SNP) | VAF 30/544 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- COL16A1 | c.455A>T p.D152V | Missense Mutation (SNP) | VAF 22/305 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- COLGALT1 | c.170C>G p.A57G | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.135); called by muse, mutect2
- ETV4 | c.839T>A p.L280H | Missense Mutation (SNP) | VAF 24/470 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.136); called by muse, mutect2
- GTSE1 | c.2113A>G p.K705E | Missense Mutation (SNP) | VAF 51/503 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- HNF1A | c.1691C>A p.T564N | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- KCNA10 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 20/446 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KPNB1 | c.8T>G p.L3R | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- MED1 | c.3031A>G p.K1011E | Missense Mutation (SNP) | VAF 66/719 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- MINK1 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MOV10 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 50/698 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); called by muse, mutect2
- NEB | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 39/528 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- PCDHB7 | c.1297A>T p.T433S | Missense Mutation (SNP) | VAF 90/1074 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.85); called by muse, mutect2
- PLG | c.1912G>T p.G638C | Missense Mutation (SNP) | VAF 46/576 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- PP2D1 | c.557A>T p.N186I | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- PQBP1 | c.420G>C p.R140S | Missense Mutation (SNP) | VAF 32/618 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.966); called by muse, mutect2
- PRKCB | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 36/492 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.33); called by muse, mutect2
- PTPRM | c.2338A>T p.T780S | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.956); called by muse, mutect2
- THOC2 | c.2806G>T p.D936Y | Missense Mutation (SNP) | VAF 27/378 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- TMEM141 | c.7A>G p.N3D | Missense Mutation (SNP) | VAF 38/423 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.077); called by muse, mutect2
- XPO7 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 11/172 reads (6%) | called by muse, mutect2
- ZPBP | c.646T>A p.C216S | Missense Mutation (SNP) | VAF 70/582 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCA10 | c.4422G>A p.K1474= | Silent (SNP) | VAF 12/378 reads (3%) | called by muse, mutect2
- C3orf20 | c.2313G>A p.L771= | Silent (SNP) | VAF 24/462 reads (5%) | called by muse, mutect2
- DIAPH2 | c.516G>T p.S172= | Silent (SNP) | VAF 32/346 reads (9%) | catalogued as rs1434413075, COSV100233640, COSV100234479, COSV61280146; called by muse, mutect2
- GABRA5 | c.342C>T p.P114= | Silent (SNP) | VAF 76/845 reads (9%) | called by muse, mutect2
- HOXA3 | c.459A>G p.K153= | Silent (SNP) | VAF 83/1006 reads (8%) | called by muse, mutect2
- HSP90AA1 | c.1236C>T p.I412= | Silent (SNP) | VAF 64/460 reads (14%) | called by muse, mutect2, varscan2
- NLGN4Y | c.1803C>T p.N601= | Silent (SNP) | VAF 62/499 reads (12%) | catalogued as rs1488646696; called by muse, mutect2, varscan2
- OR10D3 | c.567T>C p.C189= | Silent (SNP) | VAF 40/442 reads (9%) | called by muse, mutect2
- PTCH2 | c.1110C>T p.N370= | Silent (SNP) | VAF 37/444 reads (8%) | catalogued as rs575126296, COSV64710205; called by muse, mutect2
- TONSL | c.190C>T p.L64= | Silent (SNP) | VAF 23/595 reads (4%) | called by muse, mutect2
- UGDH | c.888A>T p.V296= | Silent (SNP) | VAF 16/283 reads (6%) | called by muse, mutect2
- ZFP91 | c.1074A>G p.Q358= | Silent (SNP) | VAF 22/185 reads (12%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+2774A>G | Intron (SNP) | VAF 20/656 reads (3%) | called by muse, mutect2
- C8orf44-SGK3 | c.-121-25788T>C | Intron (SNP) | VAF 20/439 reads (5%) | called by muse, mutect2
- FAM20A | c.*1708T>A | 3'UTR (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- FOXL2NB | c.220+142G>T | Intron (SNP) | VAF 24/346 reads (7%) | called by muse, mutect2
- MIER1 | chr1:66926226 A>G | 5'Flank (SNP) | VAF 22/604 reads (4%) | called by muse, mutect2
- TMEM65 | c.-25G>T | 5'UTR (SNP) | VAF 19/268 reads (7%) | catalogued as rs1362866151; called by muse, mutect2
